Somatic mutation profile of tumor specimen TCGA-SR-A6MX-01A (aliquot TCGA-SR-A6MX-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Nervous system, NOS; Age at diagnosis: 55.3 years (20,186 days).
Specimen TCGA-SR-A6MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c740160-5144-4228-a10f-5ba1a0249890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MX-10A (Blood Derived Normal), aliquot TCGA-SR-A6MX-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd8be0a5-f8a7-49ef-9609-d01ebc58c4b7

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 14, Silent 10, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6875del p.P2292Qfs*28 | Frame Shift Del (DEL) | VAF 58/101 reads (57%) | catalogued as COSV100970927; called by mutect2, pindel, varscan2
- BATF | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs1273785872, COSV54375188; called by muse, mutect2, varscan2
- FKBP9 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV54231290; called by muse, mutect2, varscan2
- GABRA4 | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99974284; called by muse, mutect2, varscan2
- LAMC1 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs548688323, COSV51140034; called by muse, mutect2, varscan2
- LIN9 | c.1112G>A p.R371Q (on ENST00000366808 / NM_001270410.2; = p.R316Q on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201671299; called by muse, mutect2, varscan2
- NLRP12 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as rs534882841; called by muse, mutect2
- SETD2 | c.6110C>G p.T2037R | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs914740277; called by muse, mutect2, varscan2
- ZNF777 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs747852923; called by muse, mutect2, varscan2
- ZNHIT1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs771133778; called by muse, mutect2, varscan2
- ITPR3 | c.5191G>A p.E1731K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- KLHL22 | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MUC17 | c.10718A>T p.E3573V | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TGDS | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRHDE | c.2787T>A p.N929K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL11B | c.27G>C p.P9= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1421171191; called by muse, mutect2, varscan2
- CHERP | c.2097C>T p.H699= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs749039686, COSV52225177; called by muse, mutect2, varscan2
- CIC | c.345G>T p.G115= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CORO7 | c.2415G>A p.Q805= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs763232660, COSV99228061; called by muse, mutect2, varscan2
- GAA | c.1410C>T p.N470= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs886043068, COSV100163641; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MPDZ | c.2052A>G p.T684= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs1217486746; called by muse, mutect2, varscan2
- MPHOSPH9 | c.639A>G p.K213= | Silent (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- PAX1 | c.1098C>T p.P366= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as rs201381441, COSV68272584; called by muse, mutect2, varscan2
- TAS2R3 | c.384G>A p.R128= | Silent (SNP) | VAF 35/129 reads (27%) | called by muse, mutect2, varscan2
- TCF25 | c.9C>G p.R3= | Silent (SNP) | VAF 8/9 reads (89%) | called by muse, varscan2
